Somatic mutation profile of tumor specimen 0DSWZ8 from CCDI case PBCIPI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.5 years (4,198 days).
Specimen 0DSWZ8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 213a6331-b9e8-45ac-b036-a478ea18f6b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSWZ2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f343370-00e8-49a8-aae7-b57f45ca2694

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, 3'UTR 3, Silent 3, Intron 2, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 267/766 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 214/868 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 222/607 reads (37%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP8B1 | c.1798C>T p.R600W | Missense Mutation (SNP) | VAF 356/1084 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780186596, CM043820; called by muse, mutect2
- CA2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 51/966 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs201928238; ClinVar: uncertain significance; called by muse, mutect2
- CIT | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 62/817 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs1216561344; called by muse, mutect2
- DDX3X | c.1045G>A p.D349N (on ENST00000399959; = p.D350N on NM_001356.5) | Missense Mutation (SNP) | VAF 276/790 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863450; called by muse, mutect2, varscan2
- FAM47A | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 452/1226 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs764123221, COSV60495125; called by muse, mutect2, varscan2
- ITPKB | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 65/621 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs1558103711; called by muse, mutect2, varscan2
- KCNA5 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 310/693 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as rs150208806, COSV52906300; called by muse, mutect2, varscan2
- NF1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 303/778 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as rs754343223, CM122058, COSV62219339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OCM2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 291/923 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777688959, COSV57535046; called by muse, mutect2, varscan2
- RBBP8NL | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 290/735 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1415842610, COSV53348293; called by muse, mutect2, varscan2
- TAS1R1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 251/626 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs776804403, COSV60228325; called by muse, mutect2, varscan2
- TLR8 | c.673C>T p.R225C (on ENST00000218032 / NM_138636.5; = p.R243C on NM_016610.4) | Missense Mutation (SNP) | VAF 200/640 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs757616604; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 42/1316 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CEP126 | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 154/803 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FOXA1 | c.973_988dup p.A330Gfs*90 | Frame Shift Ins (INS) | VAF 125/500 reads (25%) | called by mutect2, varscan2
- MDN1 | c.13308G>T p.L4436F | Missense Mutation (SNP) | VAF 403/621 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- SMU1 | c.1107_1108insC p.D370Rfs*19 | Frame Shift Ins (INS) | VAF 218/704 reads (31%) | called by mutect2, varscan2
- ZBTB12 | c.491del p.P164Rfs*17 | Frame Shift Del (DEL) | VAF 136/204 reads (67%) | called by mutect2, varscan2
- ZMYND15 | c.-29C>A | Splice Region (SNP) | VAF 64/183 reads (35%) | called by muse, mutect2, varscan2
- ANKFN1 | c.51T>C p.T17= | Silent (SNP) | VAF 248/763 reads (33%) | called by muse, mutect2, varscan2
- RAD52 | c.744C>T p.A248= | Silent (SNP) | VAF 370/867 reads (43%) | catalogued as rs766452005, COSV99942570; called by muse, mutect2, varscan2
- WFDC10B | c.48G>T p.L16= | Silent (SNP) | VAF 63/1717 reads (4%) | called by muse, mutect2
- ADGRG2 | c.305-36A>G | Intron (SNP) | VAF 118/438 reads (27%) | called by muse, mutect2, varscan2
- DCHS2 | n.2944G>T | RNA (SNP) | VAF 294/826 reads (36%) | catalogued as COSV59722812; called by muse, varscan2
- NAA60 | c.*118G>T | 3'UTR (SNP) | VAF 138/347 reads (40%) | called by muse, mutect2, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 10/96 reads (10%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- REG3G | c.77-57C>T | Intron (SNP) | VAF 68/195 reads (35%) | called by muse, mutect2, varscan2
- TCTEX1D1 | c.*83del | 3'UTR (DEL) | VAF 30/126 reads (24%) | called by mutect2, varscan2
